Somatic mutation profile of tumor specimen TCGA-A6-5659-01A (aliquot TCGA-A6-5659-01A-01D-A270-10) from TCGA case TCGA-A6-5659, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage I; Age at diagnosis: 82.2 years (30,028 days).
Specimen TCGA-A6-5659-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f7e6dd2-b06a-427c-ba77-2164fdfa6d07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-5659-10A (Blood Derived Normal), aliquot TCGA-A6-5659-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a3f48f6-d9d5-48f8-9a62-afdcbddbe9c2

The open-access MAF lists 218 somatic variants for this specimen: 163 protein-altering or splice-affecting, 51 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 143, Silent 51, Nonsense Mutation 12, Frame Shift Del 3, Intron 3, In Frame Del 2, Splice Region 1, Frame Shift Ins 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2097G>A p.W699* | Nonsense Mutation (SNP) | VAF 84/107 reads (79%) | catalogued as rs1060503282, CM950072, COSV57342069; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 80/175 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 110/219 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28937318, CM020301, CM100648, COSV61123792; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 38/52 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1276A>G p.T426A | Missense Mutation (SNP) | VAF 130/154 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs772861392, COSV52706497; called by muse, mutect2, varscan2
- ABCA2 | c.3227C>T p.S1076L (on ENST00000614293; = p.S1046L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs369448216; called by muse, mutect2, varscan2
- ACOX3 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs756175928, COSV62711951; called by muse, mutect2, varscan2
- ADCY2 | c.2671G>T p.A891S | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs972996270, COSV57871790; called by muse, mutect2, varscan2
- ADCY8 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV53895915, COSV53906214; called by muse, mutect2, varscan2
- ALDH8A1 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781744419, COSV55641768; called by muse, mutect2, varscan2
- ARHGAP6 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV100498142; called by muse, mutect2
- ARPP21 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 74/188 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs535145550, COSV51792286, COSV51800995; called by muse, varscan2
- ASIC5 | c.1363G>T p.A455S | Missense Mutation (SNP) | VAF 62/298 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV73332711; called by muse, mutect2, varscan2
- ASMT | c.721C>A p.P241T (on ENST00000381229; = p.P269T on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/540 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.529); catalogued as rs775384287, COSV67109842; called by muse, mutect2, varscan2
- ATG9B | c.2149C>T p.L717F | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV52489583; called by muse, mutect2, varscan2
- ATXN3L | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762941993, COSV101019396; called by muse, mutect2, varscan2
- BAIAP2 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1048795319, COSV58335272; called by muse, mutect2, varscan2
- CACNA2D3 | c.730C>T p.R244* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as rs1417940298, COSV55537866; called by muse, mutect2, varscan2
- CANT1 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV56605509; called by muse, mutect2, varscan2
- CAV3 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs116840777, CM010790, COSV57478483; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC14 | c.1855C>T p.R619C (on ENST00000488653; = p.R571C on NM_022757.5) | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs374105030, COSV59944734; called by muse, mutect2, varscan2
- CCT8L2 | c.548T>C p.L183P | Missense Mutation (SNP) | VAF 63/110 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100743053, COSV63462385; called by muse, mutect2, varscan2
- CD109 | c.614C>A p.S205Y | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV54649255; called by muse, mutect2, varscan2
- CDH10 | c.1456G>T p.A486S | Missense Mutation (SNP) | VAF 63/272 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as COSV100051511; called by muse, mutect2, varscan2
- CDH4 | c.1901C>T p.T634M | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779693148, COSV64663178; called by muse, mutect2, varscan2
- CDK12 | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101420452; called by muse, mutect2, varscan2
- CHRD | c.1527C>A p.D509E | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.216); catalogued as COSV52607821; called by muse, mutect2
- CHRNA3 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.56); PolyPhen benign (0.022); catalogued as rs777301381, COSV58776252; called by muse, mutect2, varscan2
- CHST2 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58885500; called by muse, mutect2, varscan2
- CHTF18 | c.2456C>T p.P819L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762683663, COSV99242922; called by muse, mutect2, varscan2
- CHUK | c.1438T>G p.L480V | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV64917854; called by muse, mutect2, varscan2
- CLK2 | c.284A>G p.Y95C | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.253); catalogued as rs779725189, COSV100751879; called by muse, mutect2, varscan2
- CLSTN2 | c.2122C>A p.P708T | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.631); catalogued as COSV101515721; called by muse, mutect2, varscan2
- CNOT11 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV56819782; called by muse, mutect2, varscan2
- CNTN4 | c.2192G>A p.R731Q | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs761965189, COSV61872783; called by muse, mutect2, varscan2
- COL6A6 | c.4808G>C p.G1603A | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62024755; called by muse, mutect2, varscan2
- CREB3L4 | c.636G>A p.K212= | Splice Region (SNP) | VAF 47/86 reads (55%) | catalogued as COSV55132094; called by muse, mutect2, varscan2
- CSMD3 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV52176756; called by muse, mutect2, varscan2
- CUBN | c.6793G>T p.D2265Y | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV64715397; called by muse, mutect2, varscan2
- CWF19L2 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV56512380; called by muse, mutect2, varscan2
- DHX8 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52253304; called by muse, mutect2, varscan2
- DISC1 | c.1808C>T p.T603M | Missense Mutation (SNP) | VAF 47/82 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as rs148111679, CM080195, COSV54407026; called by muse, mutect2, varscan2
- DKK2 | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 70/112 reads (63%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1172140233, COSV53397427; called by mutect2, varscan2
- DLG2 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT tolerated (0.74); PolyPhen benign (0.025); catalogued as rs776496218, COSV65839639; called by muse, mutect2, varscan2
- DLGAP2 | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as rs371264718; called by muse, mutect2, varscan2
- DLGAP2 | c.2890G>A p.D964N | Missense Mutation (SNP) | VAF 63/114 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs545242845, COSV70098004; called by muse, mutect2, varscan2
- DMD | c.5524A>G p.R1842G | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100819750; called by muse, mutect2
- DNAI3 | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as rs747622337, COSV54001312; called by muse, mutect2, varscan2
- EP300 | c.1282+1G>A p.X428_splice | Splice Site (SNP) | VAF 32/54 reads (59%) | catalogued as COSV54331805; called by muse, mutect2, varscan2
- EPG5 | c.4909C>T p.L1637F | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV56349521; called by muse, mutect2, varscan2
- FAM120AOS | c.436T>A p.C146S | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); catalogued as COSV52904762; called by muse, mutect2, varscan2
- FAM133A | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 240/257 reads (93%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.295); catalogued as COSV59075224; called by muse, mutect2, varscan2
- FAM47B | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 377/399 reads (94%) | SIFT tolerated (0.05); PolyPhen benign (0.25); catalogued as COSV61453842, COSV61456163; called by muse, mutect2, varscan2
- FAN1 | c.2351G>A p.G784D | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100755979; called by muse, mutect2
- FANCA | c.1095G>T p.M365I | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV66881578; called by muse, mutect2, varscan2
- FAT3 | c.6664A>T p.I2222F | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV53108351; called by muse, mutect2, varscan2
- FAT3 | c.7388C>T p.P2463L | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV53108376, COSV53177747; called by muse, mutect2, varscan2
- FFAR1 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 56/93 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50052516; called by muse, mutect2, varscan2
- FHOD1 | c.2783G>A p.R928H | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs781200583, COSV50760743; called by muse, mutect2, varscan2
- FMN2 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as rs1317589828, COSV100145126; called by muse, mutect2, varscan2
- FRA10AC1 | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.78); catalogued as COSV63271963; called by muse, mutect2, varscan2
- FREM1 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs780511700, COSV66530629; called by muse, mutect2, varscan2
- GDAP1L1 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 106/207 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs779006217, COSV61157121; called by muse, mutect2, varscan2
- GIMAP5 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.146); catalogued as rs752298821, COSV57529982; called by muse, mutect2, varscan2
- GOT1 | c.1172G>A p.S391N | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV63201601; called by muse, mutect2, varscan2
- HEXIM2 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs773017611, COSV56236383; called by muse, mutect2, varscan2
- HYDIN | c.7562C>T p.T2521M | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as rs74861733, COSV59249904; called by muse, mutect2, varscan2
- IKZF1 | c.676T>A p.Y226N | Missense Mutation (SNP) | VAF 106/330 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as COSV100498396; called by muse, varscan2
- INPP5B | c.1106A>G p.N369S (on ENST00000373023; = p.N289S on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs757163667, COSV65960823; called by muse, mutect2, varscan2
- IQCA1 | c.1936G>T p.V646F | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54501755; called by muse, mutect2, varscan2
- IQSEC1 | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.459); catalogued as rs754235473, COSV56223830; called by muse, mutect2, varscan2
- IRS1 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1243329079, COSV59333284, COSV59336305; called by muse, mutect2, varscan2
- ITPRID1 | c.1868G>A p.S623N | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV60074440; called by muse, mutect2, varscan2
- IVL | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.068); catalogued as COSV64216203; called by muse, mutect2, varscan2
- KCNA1 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as COSV66836436; called by muse, mutect2, varscan2
- KCNS2 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54638511; called by muse, mutect2, varscan2
- KDM4A | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV64959528; called by muse, mutect2, varscan2
- KIAA0319L | c.2498C>T p.P833L | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as rs142007809; called by muse, mutect2, varscan2
- KRT39 | c.773C>A p.S258Y | Missense Mutation (SNP) | VAF 79/161 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100842173, COSV62917211; called by muse, mutect2, varscan2
- KRTAP19-5 | c.45C>A p.Y15* | Nonsense Mutation (SNP) | VAF 55/67 reads (82%) | catalogued as COSV100478566; called by muse, varscan2
- LCE2B | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.062); catalogued as COSV100909310; called by muse, mutect2, varscan2
- LRRIQ1 | c.4057A>G p.R1353G | Missense Mutation (SNP) | VAF 14/215 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); catalogued as rs1565854173, COSV101280346; called by muse, mutect2
- MAGEC2 | c.517A>C p.K173Q | Missense Mutation (SNP) | VAF 77/139 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.538); catalogued as COSV55999274; called by muse, mutect2, varscan2
- MAST2 | c.2681G>A p.R894Q | Missense Mutation (SNP) | VAF 57/95 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.349); catalogued as rs753126429, COSV63618108; called by muse, mutect2, varscan2
- MLLT3 | c.270A>T p.K90N | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100580958; called by muse, mutect2
- MME | c.1781G>T p.G594V | Missense Mutation (SNP) | VAF 144/281 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64707342; called by muse, mutect2, varscan2
- MMP16 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs757895279, COSV54164309; called by muse, mutect2, varscan2
- MPDZ | c.5006G>A p.G1669E | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100056841; called by muse, mutect2
- MUC5B | c.6908C>T p.S2303L | Missense Mutation (SNP) | VAF 155/419 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs772020683, COSV71592011; called by muse, mutect2, varscan2
- MYC | c.437C>T p.S146L (on ENST00000377970; = p.S161L on NM_002467.6) | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV52367052; called by muse, mutect2, varscan2
- MYO1E | c.1487A>G p.N496S | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as COSV55686943; called by muse, mutect2, varscan2
- MYT1L | c.1880C>T p.T627M | Missense Mutation (SNP) | VAF 85/181 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV101221047, COSV67712558; called by muse, mutect2, varscan2
- NAALADL2 | c.1606A>C p.S536R | Missense Mutation (SNP) | VAF 182/360 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV69156110; called by muse, varscan2
- NIPBL | c.6182C>T p.P2061L | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs587783999, COSV56950900; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOTCH1 | c.5944C>T p.R1982W | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764422420, COSV99488070; called by muse, mutect2, varscan2
- NPAS1 | c.1175G>A p.S392N | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0.124); catalogued as rs1287733031, COSV99451389; called by muse, mutect2, varscan2
- NRXN2 | c.840G>T p.Q280H | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.465); catalogued as COSV55453005; called by muse, mutect2, varscan2
- NXPH2 | c.597G>T p.K199N | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55642462, COSV99740627; called by muse, mutect2
- OGDH | c.2912C>T p.P971L | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV56049633; called by muse, mutect2, varscan2
- OR10H2 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 72/154 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100008777; called by muse, mutect2, varscan2
- OR10J5 | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 64/118 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58385563, COSV58386029; called by muse, mutect2, varscan2
- OR2W3 | c.850C>A p.L284I | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.101); catalogued as COSV64456119, COSV64456810; called by muse, mutect2, varscan2
- OR5D18 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs775742265, COSV61737083; called by muse, mutect2, varscan2
- OTOF | c.1021G>A p.V341M | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as rs769432101, COSV55517018; called by muse, mutect2, varscan2
- OTOGL | c.4846C>T p.R1616W (on ENST00000547103; = p.R1607W on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536538111, COSV54016630; called by muse, mutect2, varscan2
- PARP9 | c.368G>A p.W123* | Nonsense Mutation (SNP) | VAF 57/104 reads (55%) | catalogued as COSV64450662; called by muse, mutect2, varscan2
- PCDH17 | c.998C>A p.A333D | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100931657; called by muse, mutect2, varscan2
- PCDHA6 | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 81/100 reads (81%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.044); catalogued as COSV65341983; called by muse, mutect2, varscan2
- PCDHGA4 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 90/110 reads (82%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.011); catalogued as rs753002448, COSV53945296; called by muse, mutect2, varscan2
- PCSK7 | c.283C>G p.H95D | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.649); catalogued as COSV100309371; called by muse, mutect2, varscan2
- PDGFRA | c.1715A>G p.Y572C | Missense Mutation (SNP) | VAF 58/95 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57267905; called by muse, mutect2, varscan2
- PHACTR3 | c.1513G>A p.V505M | Missense Mutation (SNP) | VAF 15/488 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1224648011, COSV63029751; called by muse, mutect2
- PLCB3 | c.2507C>T p.P836L | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs142407686; called by muse, mutect2, varscan2
- PODN | c.440A>C p.N147T (on ENST00000395871; = p.N99T on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV57013488; called by muse, mutect2, varscan2
- PON3 | c.712G>T p.D238Y | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55699252; called by muse, mutect2, varscan2
- POTEF | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 131/277 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.948); catalogued as rs754169172, COSV62541227; called by muse, mutect2, varscan2
- PPFIA2 | c.2852G>A p.R951H | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61020166; called by muse, mutect2, varscan2
- PPP1R9A | c.1785A>T p.Q595H | Missense Mutation (SNP) | VAF 206/353 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV56892178; called by muse, mutect2, varscan2
- PPP2R2B | c.119C>T p.A40V (on ENST00000394409; = p.A106V on NM_181674.2) | Missense Mutation (SNP) | VAF 49/63 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1554126530, COSV60764226; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRR19 | c.653G>T p.S218I | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV56625255; called by muse, mutect2, varscan2
- PTPRU | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs775440824, COSV60527630; called by muse, mutect2, varscan2
- RADIL | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs1177781598, COSV68199994; called by muse, mutect2, varscan2
- RGS20 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.323); catalogued as rs550487524, COSV52016836; called by muse, mutect2, varscan2
- RPS6KA2 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as COSV99690880; called by muse, mutect2, varscan2
- RXRB | c.484A>T p.I162F | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.551); catalogued as COSV63399705; called by muse, mutect2, varscan2
- SAMD7 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 56/164 reads (34%) | catalogued as COSV59418650; called by muse, mutect2, varscan2
- SCN9A | c.4351T>G p.L1451V (on ENST00000303354; = p.L1440V on NM_002977.3) | Missense Mutation (SNP) | VAF 205/535 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57609404; called by muse, mutect2, varscan2
- SCRN1 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs766147656, COSV54130661; called by muse, mutect2, varscan2
- SLC12A3 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs772187470, CM117099, COSV52634825; called by muse, mutect2, varscan2
- SLC22A2 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs768194904, COSV65266300; called by muse, mutect2, varscan2
- SMARCE1 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 39/124 reads (31%) | catalogued as rs1251821702, COSV52860590; called by muse, mutect2, varscan2
- SNPH | c.396G>T p.Q132H | Missense Mutation (SNP) | VAF 107/201 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67870605; called by muse, mutect2, varscan2
- SORCS1 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV53848358, COSV53865482; called by muse, mutect2, varscan2
- SPATA18 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs779355129, COSV54644470; called by muse, varscan2
- STON1 | c.1713C>A p.H571Q | Missense Mutation (SNP) | VAF 72/153 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.776); catalogued as rs1262877194, COSV59130422; called by muse, mutect2, varscan2
- TBC1D22B | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.913); catalogued as rs767058134, COSV65142535; called by muse, mutect2, varscan2
- TCHHL1 | c.846G>T p.K282N | Missense Mutation (SNP) | VAF 82/151 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.22); catalogued as COSV64285688; called by muse, mutect2, varscan2
- TDRD7 | c.3121C>T p.R1041* | Nonsense Mutation (SNP) | VAF 70/145 reads (48%) | catalogued as COSV62429379, COSV62430190; called by muse, mutect2, varscan2
- TMEM132B | c.1940C>T p.T647M | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750179973, COSV54766965; called by muse, mutect2, varscan2
- TNFRSF11A | c.545T>C p.V182A | Missense Mutation (SNP) | VAF 58/70 reads (83%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV54023414; called by muse, mutect2, varscan2
- TOP1 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 25/276 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.271); catalogued as COSV100793824; called by muse, mutect2
- TRIM3 | c.1376C>A p.T459K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV100624408; called by muse, mutect2, varscan2
- TSPEAR | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 53/66 reads (80%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as rs113059777, COSV59959310, COSV59961665; called by muse, mutect2, varscan2
- TTC9 | c.558C>A p.Y186* | Nonsense Mutation (SNP) | VAF 34/79 reads (43%) | catalogued as COSV56448182; called by muse, mutect2, varscan2
- TTK | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 63/476 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1260979404, COSV57883719; called by muse, mutect2, varscan2
- TUBGCP6 | c.2068C>T p.R690W | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774338870, COSV50541673; called by muse, mutect2, varscan2
- UNC13C | c.5171C>A p.S1724Y | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.48); catalogued as rs1415421209, COSV52871562; called by muse, mutect2, varscan2
- UNC5A | c.1540C>T p.R514W | Missense Mutation (SNP) | VAF 100/123 reads (81%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs749730825, COSV52839070; called by muse, mutect2, varscan2
- VARS1 | c.1303G>A p.G435S | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65155180; called by muse, mutect2, varscan2
- VPS13A | c.1883G>A p.R628H | Missense Mutation (SNP) | VAF 120/302 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62429527; called by muse, mutect2, varscan2
- XKR6 | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 29/39 reads (74%) | catalogued as COSV58656108; called by muse, mutect2, varscan2
- ZDBF2 | c.4241C>T p.S1414F | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65625771; called by muse, mutect2, varscan2
- ZNF408 | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs971021664, COSV61238129; called by muse, mutect2, varscan2
- ZNF530 | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 49/131 reads (37%) | catalogued as rs780728808, COSV60531517; called by muse, mutect2, varscan2
- ZNF607 | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV67696823; called by muse, mutect2, varscan2
- ZNF676 | c.1826G>T p.S609I (on ENST00000650058; = p.S577I on NM_001001411.3) | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.373); catalogued as COSV68093035; called by muse, mutect2, varscan2
- AFDN | c.387_389del p.K129del | In Frame Del (DEL) | VAF 66/167 reads (40%) | called by mutect2, pindel, varscan2
- CC2D1B | c.1549del p.L517Cfs*53 | Frame Shift Del (DEL) | VAF 55/116 reads (47%) | called by mutect2, pindel, varscan2
- IPMK | c.920_921del p.E307Vfs*31 | Frame Shift Del (DEL) | VAF 30/90 reads (33%) | called by pindel, varscan2
- KIAA0232 | c.2353dup p.T785Nfs*3 | Frame Shift Ins (INS) | VAF 33/132 reads (25%) | called by mutect2, varscan2
- MAF | c.997_999del p.E333del | In Frame Del (DEL) | VAF 27/79 reads (34%) | called by mutect2, pindel, varscan2
- MED12L | c.744del p.K248Nfs*5 | Frame Shift Del (DEL) | VAF 75/259 reads (29%) | called by mutect2, pindel, varscan2
- ALS2 | c.396G>A p.P132= | Silent (SNP) | VAF 75/194 reads (39%) | catalogued as rs374978798; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- AMOTL1 | c.432C>T p.L144= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as rs1328174556, COSV100133792; called by muse, mutect2, varscan2
- CCDC141 | c.3807T>C p.P1269= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV55373275; called by muse, mutect2, varscan2
- CD40 | c.273C>A p.V91= | Silent (SNP) | VAF 54/141 reads (38%) | catalogued as COSV64847780; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1005C>T p.T335= (on ENST00000357886 / NM_001365728.1; = p.T321= on NM_016082.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 153/302 reads (51%) | catalogued as COSV59426826; called by muse, mutect2, varscan2
- COL22A1 | c.4755G>A p.G1585= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as rs1454010642, COSV100278557; called by muse, mutect2
- COL6A3 | c.8637G>A p.T2879= | Silent (SNP) | VAF 61/155 reads (39%) | catalogued as rs1417532835, COSV55088973; called by muse, mutect2, varscan2
- CPAMD8 | c.5496C>T p.D1832= (on ENST00000651564; = p.D1785= on NM_015692.5) | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV99935255; called by muse, mutect2, varscan2
- CPXM2 | c.1692C>T p.D564= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as rs547897756, COSV53861729; called by muse, mutect2, varscan2
- CYP1A2 | c.1305C>T p.A435= | Silent (SNP) | VAF 46/77 reads (60%) | catalogued as rs745999166, COSV59659682; called by muse, mutect2, varscan2
- DCTPP1 | c.468G>T p.G156= | Silent (SNP) | VAF 43/81 reads (53%) | catalogued as COSV100073538; called by muse, mutect2, varscan2
- DGKI | c.351G>A p.A117= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99934628; called by muse, mutect2, varscan2
- ELSPBP1 | c.369T>C p.N123= | Silent (SNP) | VAF 9/161 reads (6%) | catalogued as COSV100353630; called by muse, mutect2
- ESRP2 | c.1350C>T p.S450= (on ENST00000565858 / NM_001365264.1; = p.S440= on NM_024939.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as rs372468822; called by muse, mutect2, varscan2
- FKBP9 | c.1524C>T p.V508= | Silent (SNP) | VAF 44/170 reads (26%) | catalogued as COSV54230741; called by muse, mutect2, varscan2
- GABRD | c.135C>T p.D45= | Silent (SNP) | VAF 51/104 reads (49%) | catalogued as rs754323369, COSV66080540; ClinVar: likely benign; called by muse, mutect2, varscan2
- GJB5 | c.723C>T p.D241= | Silent (SNP) | VAF 47/136 reads (35%) | catalogued as rs536768375, COSV58356165; called by muse, mutect2, varscan2
- GPR179 | c.1014C>T p.F338= (on ENST00000621958; = p.F337= on NM_001004334.4) | Silent (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- GRIA4 | c.2370C>T p.Y790= | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as rs762639803, COSV56895709; called by muse, mutect2, varscan2
- IGHG1 | c.204G>A p.V68= | Silent (SNP) | VAF 56/127 reads (44%) | called by muse, mutect2, varscan2
- ITIH5 | c.1911C>T p.H637= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as rs572386195, COSV53671612, COSV99904666; called by muse, mutect2, varscan2
- LAMP3 | c.738G>A p.L246= | Silent (SNP) | VAF 55/150 reads (37%) | catalogued as COSV55614833, COSV55615604; called by muse, mutect2, varscan2
- LSG1 | c.282C>T p.F94= | Silent (SNP) | VAF 73/138 reads (53%) | catalogued as rs755607314, COSV54570113; called by muse, mutect2, varscan2
- MRGPRE | c.894C>T p.A298= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs561025507, COSV101100019; called by muse, mutect2, varscan2
- NAT10 | c.1647C>T p.S549= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as rs577046723, COSV57663760, COSV57666589; called by muse, mutect2, varscan2
- NDUFS6 | c.267C>T p.G89= | Silent (SNP) | VAF 61/106 reads (58%) | catalogued as rs769132703, COSV56876656; called by muse, mutect2, varscan2
- NEXMIF | c.1122G>T p.G374= | Silent (SNP) | VAF 125/134 reads (93%) | catalogued as COSV50030530; called by muse, mutect2, varscan2
- NKD2 | c.1182G>A p.S394= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs1421705805, COSV56891360; called by muse, mutect2, varscan2
- OBSCN | c.7251G>A p.T2417= | Silent (SNP) | VAF 67/123 reads (54%) | catalogued as rs371761770, COSV52778616; called by muse, mutect2, varscan2
- OR52E6 | c.480A>T p.P160= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as COSV61432058; called by muse, mutect2, varscan2
- OR6C74 | c.372C>A p.I124= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV59606424; called by muse, mutect2, varscan2
- PARP14 | c.1752C>T p.A584= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as rs951694337, COSV71734663; called by muse, mutect2, varscan2
- PCDH17 | c.162C>T p.G54= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV100931655; called by muse, mutect2, varscan2
- PCDHA5 | c.1278G>A p.A426= | Silent (SNP) | VAF 99/132 reads (75%) | catalogued as COSV65352344; called by muse, mutect2, varscan2
- PLEKHA5 | c.1203C>T p.A401= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs150691984; called by muse, mutect2, varscan2
- PRSS12 | c.2157A>C p.R719= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV99628271; called by muse, mutect2, varscan2
- PSMB10 | c.366G>A p.L122= | Silent (SNP) | VAF 47/95 reads (49%) | catalogued as rs772788981, COSV50452772; called by muse, mutect2, varscan2
- RASGRF2 | c.2037G>T p.L679= | Silent (SNP) | VAF 82/105 reads (78%) | catalogued as COSV99429267; called by muse, varscan2
- REG1B | c.399T>C p.N133= | Silent (SNP) | VAF 55/150 reads (37%) | catalogued as COSV59305537; called by muse, mutect2, varscan2
- RYR1 | c.4089G>A p.A1363= | Silent (SNP) | VAF 93/233 reads (40%) | catalogued as rs761793739, COSV62107582; called by muse, mutect2, varscan2
- SELENOO | c.1047C>T p.Y349= | Silent (SNP) | VAF 60/98 reads (61%) | catalogued as rs529648565, COSV101096802; called by muse, mutect2, varscan2
- SH2B2 | c.162C>T p.A54= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV60826292; called by muse, varscan2
- STAB1 | c.5187C>T p.T1729= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs771251910, COSV58735998; called by muse, mutect2, varscan2
- TFAP2D | c.321C>T p.H107= | Silent (SNP) | VAF 54/124 reads (44%) | catalogued as COSV50415159; called by muse, mutect2, varscan2
- TPR | c.336A>G p.Q112= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs368470841; called by muse, mutect2, varscan2
- TSPOAP1 | c.2346G>A p.P782= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as rs746732636, COSV52108360; called by muse, mutect2, varscan2
- TTN | c.4611C>A p.G1537= (on ENST00000591111; = p.G1491= on NM_003319.4) | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as COSV59870835; called by muse, mutect2, varscan2
- WDR24 | c.1143C>T p.I381= (on ENST00000248142; = p.I251= on NM_032259.4) | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as rs749577638, COSV50197522; called by muse, mutect2, varscan2
- XDH | c.2139G>T p.L713= | Silent (SNP) | VAF 47/126 reads (37%) | catalogued as COSV65148593; called by muse, mutect2, varscan2
- ZNF219 | c.1368G>A p.P456= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as COSV53880288; called by muse, mutect2, varscan2
- ZNF493 | c.1548C>T p.L516= | Silent (SNP) | VAF 48/145 reads (33%) | catalogued as rs760617541, COSV62750013; called by muse, mutect2, varscan2
- GATA3 | chr10:8051081 A>G | 5'Flank (SNP) | VAF 30/65 reads (46%) | catalogued as rs757480024; called by muse, mutect2, varscan2
- GCNT2 | c.926-34760G>A | Intron (SNP) | VAF 106/219 reads (48%) | catalogued as rs776266980, COSV53942266, COSV99399141; called by muse, mutect2, varscan2
- TTN | c.10361-4501G>T | Intron (SNP) | VAF 44/109 reads (40%) | catalogued as COSV60048958; called by muse, mutect2, varscan2
- UGT1A6 | c.862-23336C>T | Intron (SNP) | VAF 59/142 reads (42%) | catalogued as rs368889261; called by muse, mutect2, varscan2
